Somatic mutation profile of tumor specimen TCGA-XJ-A83F-01A (aliquot TCGA-XJ-A83F-01A-11D-A34U-08) from TCGA case TCGA-XJ-A83F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A83F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c45f94b4-ac57-4499-a54b-c76bbc1f1799.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A83F-10A (Blood Derived Normal), aliquot TCGA-XJ-A83F-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51c000d0-2ba1-4dfc-a702-87706466cfbb

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, In Frame Del 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.1746_1748del p.F582del | In Frame Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs780063509; called by pindel, varscan2
- ABCB9 | c.1867G>A p.G623S (on ENST00000280560 / NM_019625.4; = p.G580S on NM_019624.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs147328787, COSV99757702; called by muse, mutect2, varscan2
- AHR | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.263); catalogued as COSV99619877; called by muse, mutect2, varscan2
- ALMS1 | c.4856C>T p.A1619V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs1085307684, COSV100042914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD33 | c.418G>C p.A140P (on ENST00000340970 / NM_001304459.2; = p.A265P on NM_182608.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV100001385; called by muse, mutect2
- ATP2A1 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV63920433; called by muse, mutect2, varscan2
- CDC42BPG | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs200874110, COSV61347947; called by muse, mutect2, varscan2
- COL7A1 | c.6395G>A p.G2132D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs755669902, CM992850, COSV100096759; called by muse, mutect2, varscan2
- FCRL3 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV100943377; called by muse, varscan2
- GTPBP3 | c.1279C>G p.P427A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100258979; called by muse, mutect2, varscan2
- H2BC13 | c.296T>A p.V99E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100704406; called by muse, mutect2, varscan2
- HUNK | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs773621924, COSV99528651; called by muse, mutect2, varscan2
- KCNK17 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs753483930, COSV100949035; called by muse, mutect2, varscan2
- LARP1 | c.786A>C p.E262D (on ENST00000518297 / NM_033551.3; = p.E185D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100303884; called by muse, mutect2, varscan2
- LRRK2 | c.5458G>A p.E1820K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs764408585, COSV100110652; called by muse, mutect2, varscan2
- MC4R | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs13447332, CM121075, CM990834, COSV55352467; called by muse, mutect2, varscan2
- MYH15 | c.2084T>C p.I695T | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1371097497, COSV99843683; called by muse, mutect2, varscan2
- OR8D4 | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1283262220, COSV100361860; called by muse, mutect2, varscan2
- PPFIBP1 | c.2585T>A p.L862Q (on ENST00000318304 / NM_177444.3; = p.L856Q on NM_003622.4) | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945017; called by muse, mutect2, varscan2
- SDK1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV101269562; called by muse, mutect2, varscan2
- SERPINF2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132005; called by muse, mutect2, varscan2
- SLC12A2 | c.3131C>T p.T1044M | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs375675214; called by muse, mutect2, varscan2
- STOX2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs966906197, COSV100408215; called by muse, mutect2
- TTN | c.18985T>C p.C6329R (on ENST00000591111; = p.C5402R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/216 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV100619243; called by muse, mutect2, varscan2
- ZNF445 | c.2176G>T p.V726F | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101253821; called by muse, mutect2, varscan2
- HIRA | c.1575del p.S526Vfs*14 | Frame Shift Del (DEL) | VAF 49/157 reads (31%) | called by mutect2, pindel, varscan2
- EEF1AKNMT | c.1185C>T p.S395= (on ENST00000361735 / NM_015935.5; = p.S309= on NM_014955.3) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs369151040; called by muse, mutect2, varscan2
- FLT4 | c.3957G>A p.R1319= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99987649; called by muse, mutect2, varscan2
- NCF1 | c.651C>T p.D217= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs376919169; called by muse, mutect2
- SYNE1 | c.6813G>A p.P2271= (on ENST00000367255 / NM_182961.4; = p.P2278= on NM_033071.3) | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as rs138911730, COSV99569927; called by muse, mutect2, varscan2
- SYNE1 | c.4686A>G p.R1562= (on ENST00000367255 / NM_182961.4; = p.R1569= on NM_033071.3) | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV99569938; called by muse, mutect2, varscan2
- ZNF835 | c.765C>T p.C255= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs751691375, COSV73379427; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827917 G>A | 3'Flank (SNP) | VAF 3/37 reads (8%) | catalogued as rs1556946187, COSV59428943; called by muse, mutect2
